Gene-level copy-number profile of tumor specimen C3L-07580-54 from CPTAC case C3L-07580, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 81.3 years (29,689 days).
Specimen C3L-07580-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d38da9f-0b7b-4d34-a678-1fb98ca51cdf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07580-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/5982281f-2aec-4388-a760-3d43abb462de

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 3,595; copy number 3: 2,425; copy number 4: 48,618; copy number 5: 2,824; copy number 6: 572; copy number 7: 11; copy number 12: 226; copy number 13: 36; copy number 16: 6; copy number 23: 23; copy number 27: 57.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 348 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:7,958,573–8,981,342, 39 genes, copy number 12–16: ELAVL1, AC010336.6, AC008946.1, CCL25, FBN3, AC022146.1, CERS4, AC022146.2, CD320, AC010323.1, NDUFA7, RPS28, KANK3, AC010323.2, ANGPTL4, RAB11B-AS1, MIR4999, RAB11B, MARCHF2, AC136469.1, AC136469.2, HNRNPM, PRAM1, ZNF414, MYO1F, AC092316.1, ADAMTS10, AC130469.1, NFILZ, AC243312.1, ACTL9, OR2Z1, RPL23AP78, AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16.
- chr19:10,037,803–12,513,854, 150 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr19:13,206,442–14,419,383, 43 genes, copy number 12: CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A.
- chr19:16,352,462–18,333,573, 116 genes, copy number 13–27 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
